Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RD, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RD-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8950/3
Site C6CF Uterus NOS C55.9
path Endometrium C54.1
JW 4/2/13

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Pelvic disease
- 3: SP: Omentum
- 4: SP: Pelvic peritoneum
- 5: SP: Right external iliac lymph nodes

DIAGNOSIS:

1. UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- CARCINOSARCOMA (MALIGNANT MIXED MULLERIAN TUMOR) OF ENDOMETRIUM, WITH HETEROLOGOUS ELEMENTS COMPOSED OF LIPOSARCOMA, CHONDROSARCOMA AND RHABDOMYOSARCOMA.
- THE TUMOR INVADES TO > HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 9 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 11 MM.
- ENDOCERVICAL INVASION IS PRESENT IN THE MUCOSA AND STROMA.
- ENDOCERVICAL STROMAL INVASION IS SUPERFICIAL (<1 MM).
- VASCULAR INVASION IS PRESENT.
- THE LEFT OVARY SHOWS MICROSCOPIC FOCUS OF METASTATIC TUMOR ON THE SURFACE.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
2. "PELVIC DISEASE"; BIOPSY:
- METASTATIC CARCINOSARCOMA.
3. OMENTUM; OMENTECTOMY:
- METASTATIC CARCINOSARCOMA.
4. PERITONEUM, PELVIC; BIOPSY:
- METASTATIC CARCINOSARCOMA.
5. LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

[page 2 of 2]
[REDACTED]

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

Criteria	12/31/18		No
Prior Pathology / History			/
Discrepancy / Primary No.			/
Reviewer Initials	B. [REDACTED]	Date Reviewed: 12/30/18	

Source: NCI Genomic Data Commons file a2e9370a-4ba1-499f-9cf5-24d91474a3f3 (TCGA-N5-A4RD.D309E728-C6C7-4A38-AD9E-4C6C41491DB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).